Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A669, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A669-02A (Recurrent Tumor).

[page 1 of 2]
Surgical Pathology Surgicals

Surgical Pathology Consultation / Department of Pathology

[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

Oligodendroglioma, anaplastic
945113
Site Brain, subcortical lesion
271.8
CCF Brain, supratentorial NOS
271.0
JW 4/23/13

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

A. Tumor [REDACTED] A. Frozen Section Charge [REDACTED] B. Tumor [REDACTED]

CLINICAL HISTORY: [REDACTED] year old male with history of anaplastic oligodendroglioma. Left parietal-occipital resection [REDACTED]. Declined chemotherapy and radiation therapy. Recurrence of his symptoms of left/right disorientation, visual spatial disorientation. Found to have an enhancing lesion of the left parieto-occipital regions with new subependymal spread along left lateral ventricle.

GROSS DESCRIPTION:

Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #:

- A. "Tumor"
- B. "Tumor"

A. The specimen is received without fixative and consists of two irregular pieces of pink to red, semi-gelatinous soft tissue, measuring 0.8 x 0.7 x 0.2 cm, and 1.9 x 1.2 x 0.5 cm. The smaller of the two pieces is submitted entirely for frozen section; the frozen section diagnosis is "Malignant glioma, compatible with anaplastic oligodendroglioma; final classification deferred to permanents" per Dr. [REDACTED].

The frozen tissue is resubmitted in FSA1, and the remaining tissue is further sectioned and submitted in A2, for permanent processing. [REDACTED]

B. The specimen is received without fixative and consists of multiple irregular pieces of pink-tan to red soft tissue, measuring 4.7 x 3.9 x 0.6 cm in aggregate. A portion of the specimen is submitted to the Tumor Bank for research. [REDACTED]

DIAGNOSIS:

A. "Tumor", biopsy: Anaplastic oligodendroglioma (see comment)

B. "Tumor", excision: Anaplastic oligodendroglioma (see comment)

Comment: The tumor present in these specimens closely resembles that in a previous sample [REDACTED].

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

[REDACTED]
[REDACTED]

[page 2 of 2]
Note: Test systems have been developed and their performance characteristics determined by [redacted]. Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Pathologist [redacted]

Top of Page

Recurrent tumor: anaplastic oligodendroglioma

Hist AA Discrepancy		☒
Concurrent/Synchronous Primary Note		☒

bw 4/5/13

Source: NCI Genomic Data Commons file 06dec69a-d80a-4054-8e8c-fa046c1e050b (TCGA-DH-A669.B34CDA94-75EB-42E4-AAF8-70C69BBDDD84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).